Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UT-01A (Primary Tumor).

[page 1 of 3]
Item	Yes	No
Significant Discrepancy		
PAA Discrepancy		
or Malignancy History		
viewer Initials	RA	Date Reviewed: 1/10/10

ICD-0-3
Adenocarcinoma, Endometrioid, NOS 8380/3
Site: Endometrium C54.1 w 5/1/11

Surgical Pathology Report

Patient Name:

Med Rec No:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

Pt. Phone no

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Adenocarcinoma

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Enlarged left pelvic lymph nodes
- B: Left ovary
- C: Right ovary
- D: Uterus, cervix
- E: Left pelvic lymph nodes
- F: Left aortic lymph node
- G: Right pelvic lymph nodes
- H: Right caval lymph node

DIAGNOSIS:

- A. Enlarged left pelvic lymph nodes: Three lymph nodes negative for metastasis (0/3)
- B. Left ovary: Tube and ovary with no evidence of tumor
- C. Right ovary: Tube and ovary with no evidence of tumor
- D. Uterus, cervix: ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with staging
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 2
Nuclear grade:	2
Tumor size:	2.5 cm
Extent of invasion:	Less than 50% (4mm invasion; 12mm myometrial thickness)
Lymphovascular invasion:	Not identified
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical Involvement:	Direct cervical stromal extension
Right adnexa:	No evidence of tumor
Left adnexa:	No evidence of tumor
Other findings:	Intramural leiomyomata
Special studies:	On request

Regulatory Statement:

The following statement may be applicable to some of the reagents and/or methods used in developing the above report. This test was developed and its performance characteristics determined by the manufacturer and approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

Staging information:

T2b, N0

- E. Left pelvic lymph nodes: Five lymph nodes negative for metastasis (0/5)
- F. Left aortic lymph node: Two lymph nodes negative for metastasis (0/2)
- G. Right pelvic lymph nodes: Fourteen lymph nodes negative for metastasis (0/14)
- H. Right caval lymph node: Three lymph nodes negative for metastasis (0/3)

Intraoperative Consultation:

Touch Preparation: Benign

Gross Description

- A. Received fresh for intraoperative consultation labeled "[redacted] left pelvic lymph node" are three fragments of tan-yellow fatty soft tissue, up to 5.0 cm, 22.0 gms overall. By palpation and cross sectioning, there are multiple soft, tan-pink rubbery lymphoid nodules, up to 2.0 x 1.5 cm across. Touch imprints are prepared and stained with Diff-Quik solution. A representative section of each lymphoid nodule, blocks A1-A5.
- B. Received in formalin labeled "[redacted] left ovary" is a fimbriated segment of ligated fallopian tube and attached ovary, 12.0 gms overall. The fallopian tube, approximately 4.5 x 0.3 cm. Its cut surface is pinpoint and grossly free of pathologic change. The ovary, 2.0 x 1.2 x 1.0 cm, 3.0 gms. A portion of the tissue is removed intraoperatively and submitted for cancer research. Upon sectioning, the cut surface reveals mottled, tan-yellow ovarian parenchyma with an occasional corpora albicans. Representative fallopian tube and ovary, block B.
- C. Received in formalin labeled "[redacted] right ovary" is a fimbriated segment of ligated fallopian tube and attached ovary, 10.0 gms overall. The fallopian tube, approximately 4.5 x 0.3 cm. Its cut surface is pinpoint and grossly free of pathologic change. The ovary, 2.7 x 1.1 x 0.8 cm, 4.0 gms. A portion of the tissue is removed intraoperatively and submitted for cancer research. Upon sectioning, the cut surface reveals mottled, tan-yellow ovarian parenchyma with an occasional corpora albicans. Representative fallopian tube and ovary, block C.
- D. Received in formalin labeled "[redacted] uterus and cervix" is a previously opened uterus and cervix with surgically absent bilateral adnexa, 111.0 gms. The uterus measures 7.5 cm in length, 4.5 cm in broadest width and up to 4.0 cm anterior-posteriorly. The serosa is smooth and glistening, tan-pink. The cervix measures 3.0 cm in length and 2.5 cm in maximum diameter. Its external mucosa is tan-white and non-ulcerated. Situated along the lower anterior wall of the endometrial canal is a friable, red-tan exophytic lesion, approximately 2.5 x 1.5 cm across. The cut surface of the tumor reveals it to grossly extend to a depth of 0.5 cm within the myometrium, and 3.0 cm of the cervix. At this level, the myometrium measures at least 1.2 cm in thickness. Elsewhere, the endometrium is smooth, tan-pink, 0.1 cm in thickness. A portion of the endometrium is removed intraoperatively and submitted for cancer research. Sections through the myometrium reveal multiple circumscribed, white-grey rubbery fibroids, up to 1.7 x 1.1 cm across. Their cut surface reveals a whorled architecture without gross necrosis or hemorrhage. At least one of the fibroids is calcified. Representative sections, blocks D1-D10.

Key to cassettes:

- D1 - Anterior cervix
- D2 - Posterior cervix
- D3 - Upper cervical canal, full thickness
- D4-D6 - Tumor, full thickness
- D7 - Endomyometrium, upper corpus, full thickness
- D8 - Left parametrium
- D9 - Right parametrium
- D10 - Fibroids

- E. Received in formalin labeled "[redacted] left pelvic lymph nodes" are fragments of tan-yellow fatty soft tissue, up to 4.2 x 4.1 x 1.2 cm, 12.0 grams overall. By palpation and cross sectioning, there are multiple soft, tan-pink rubbery lymphoid nodules, up to 0.9 x 0.6 cm cross. Entirely submitted, blocks E1-E2.

Key to cassettes:

- E1 - Lymphoid nodules

[page 3 of 3]
Surgical Pathology Report

E2 - Remainder of sample

- F. Received in formalin labeled "[REDACTED] left aortic node" are fragments of tan-yellow fatty soft tissue, up to 2.5 x 2.3 x 1.2 cm, 4.0 grams overall. By palpation and cross sectioning, there is a soft, tan-pink rubbery lymphoid nodule, up to 0.6 x 0.4 cm cross. Entirely submitted, blocks F1-F2.

Key to cassettes:

F1 - Lymphoid nodule
F2 - Remainder of sample

- G. Received in formalin labeled "[REDACTED] right pelvic lymph nodes" are fragments of tan-yellow fatty soft tissue, up to 6.9 x 5.2 x 2.2 cm, 29.0 grams overall. By palpation and cross sectioning, there are several soft, tan-pink rubbery lymphoid nodules, up to 0.7 x 0.5 cm across. Entirely submitted, block G1-G6

Key to cassettes:

G1 - Lymphoid nodules
G2-G6 - Remainder of sample

- H. Received in formalin labeled "[REDACTED] right caval node" are fragments of tan-yellow fatty soft tissue, up to 3.3 x 2.1 x 1.4 cm, 5.0 grams overall. By palpation and cross sectioning, there is a soft, tan-pink rubbery lymphoid nodule, 1.3 x 0.9 cm across. Entirely submitted, block H1-H2

Key to cassettes:

H1 - Lymphoid nodule
H2 - Remainder of sample

Microscopic Description

The microscopic findings support the above diagnosis.

Electronically Signed Out By [REDACTED]

Source: NCI Genomic Data Commons file ddc88160-a07b-4011-ab00-9b5565e386b0 (TCGA-BS-A0UT.326838B8-D069-4F9C-9353-F806B56DCA48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).